Surgical pathology report (de-identified scan), TCGA case TCGA-21-1071, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-1071-01A (Primary Tumor).

[page 1 of 2]
Source of Specimen(s):

A: R4

B: PORTION OF 6TH RIB

C: R9 L.N.

D: R10 L.N.

E: R11 L.N.

F: RUL

G: NO.7 L.N.

Sunquest Archived Tests:

NATURE OF SPECIMEN : RESECTION, FROZEN SECTION

Gross Description:

GROSS DESCRIPTION: Received in seven parts.

SOURCE OF TISSUE: 1. Labeled #1, "R4"

FROZEN SECTION DIAGNOSIS: 1FS - NO TUMOR SEEN.

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 0.8 Cm in greatest dimension red-purple firm lymph node. It is submitted in toto for frozen section evaluation and the frozen itself is submitted in one block.

DESIGNATION OF SECTIONS: 1FS

SUMMARY OF SECTIONS: FS-1

SOURCE OF TISSUE: 2. Labeled #2, "portion of 6th rib"

GROSS DESCRIPTION: Received fresh is a 2.0 cm in greatest dimension tan fragment of rib with attached soft tissue. A representative section is submitted in one block, following decalcification.

DESIGNATION OF SECTIONS: block 2

SUMMARY OF SECTIONS: undesignated -1

SOURCE OF TISSUE: 3. Labeled #3, "R9 lymph node"

[page 2 of 2]
- HISTOLOGIC CLASSIFICATION OF TUMOR IS SQUAMOUS CELL (EPIDERMOID) CARCINOMA, NON-KERATINIZING TYPE
- GRADE OF TUMOR IS POORLY DIFFERENTIATED
- MAXIMUM DIMENSION OF TUMOR IS 7.5 CM
- LYMPHATIC INVASION BY TUMOR IS ABSENT
- ARTERIAL INVASION BY TUMOR IS ABSENT
- INVASION INTO BUT NOT THROUGH THE PLEURA BY TUMOR IS PRESENT
- INVASION THROUGH THE PLEURA BY TUMOR IS ABSENT
- TUMOR NECROSIS IS MARKED
- SURGICAL MARGINS ARE UNINVOLVED BY TUMOR
- NON-NEOPLASTIC LUNG TISSUE SHOWS EMPHYSEMA
- TOTAL NUMBER OF NODES EXAMINED IS 20
- TOTAL NUMBER OF POSITIVE NODES IS 0
- STAGING: T2
NO

Source: NCI Genomic Data Commons file 924a0b6b-1131-45a9-9062-d360165da4a1 (TCGA-21-1071.7E0FC9AA-AF71-4605-A396-3EDF6B1870F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).